Somatic mutation profile of tumor specimen TCGA-DD-AAD1-01A (aliquot TCGA-DD-AAD1-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 51.5 years (18,794 days).
Specimen TCGA-DD-AAD1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08ffc74b-b910-49a0-abef-1f61ff2be8b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD1-10A (Blood Derived Normal), aliquot TCGA-DD-AAD1-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a9d840-db44-482a-bbd5-ca2aef9757df

The open-access MAF lists 145 somatic variants for this specimen: 107 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 37, Splice Site 5, Frame Shift Del 4, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1537A>T p.I513F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99712351; called by muse, mutect2, varscan2
- ACAP1 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99341463; called by muse, mutect2
- ADCY8 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV99651088; called by muse, mutect2
- AFTPH | c.2385T>A p.D795E | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99480377; called by muse, mutect2
- ANKRD12 | c.1401A>C p.K467N | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100040898; called by muse, mutect2, varscan2
- ANO4 | c.697T>A p.C233S (on ENST00000392977 / NM_001286615.2; = p.C198S on NM_178826.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100152202; called by muse, mutect2, varscan2
- ARHGAP15 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99708992; called by muse, varscan2
- ARHGEF5 | c.4105A>G p.I1369V | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as COSV99282622; called by muse, mutect2
- BMX | c.1400T>C p.L467P | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564334; called by muse, mutect2, varscan2
- BRCA1 | c.2024C>G p.A675G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV100523440; called by muse, mutect2, varscan2
- C18orf54 | c.354A>G p.I118M | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1267980240, COSV100266367; called by muse, mutect2, varscan2
- C2orf80 | c.295-1G>T p.X99_splice | Splice Site (SNP) | VAF 53/256 reads (21%) | catalogued as COSV100378308, COSV58016661; called by muse, mutect2, varscan2
- C8orf76 | c.59G>T p.R20M | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as COSV99414878; called by muse, mutect2, varscan2
- CARD10 | c.2780G>T p.R927L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV99324713; called by muse, mutect2, varscan2
- CDH18 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99932660; called by muse, mutect2, varscan2
- CDH24 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99399196; called by muse, mutect2
- CDYL | c.805G>T p.G269C (on ENST00000328908 / NM_001368125.1; = p.G215C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV100188864; called by muse, mutect2, varscan2
- CEMIP | c.2508C>A p.S836R | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs956497500, COSV99586256; called by muse, mutect2, varscan2
- CERS5 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs373121500; called by muse, mutect2, varscan2
- CLASRP | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.11); catalogued as COSV99673590; called by muse, mutect2, varscan2
- COL12A1 | c.6608-2A>G p.X2203_splice | Splice Site (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100485532; called by muse, mutect2, varscan2
- COL4A5 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086817; called by muse, mutect2, varscan2
- COL6A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs905662421, COSV55087815, COSV55109749; ClinVar: uncertain significance; called by muse, mutect2
- CPEB3 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99798795; called by muse, mutect2, varscan2
- CSMD1 | c.10508C>A p.S3503* (on ENST00000520002; = p.S3502* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100144841, COSV59325755; called by muse, mutect2, varscan2
- DCAF5 | c.2491A>C p.N831H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as COSV100432279; called by muse, mutect2, varscan2
- DCAF5 | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432282; called by muse, mutect2, varscan2
- ERRFI1 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as COSV101087997; called by muse, mutect2, varscan2
- FCHO1 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99405879; called by muse, mutect2, varscan2
- FER1L6 | c.3486C>G p.D1162E | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV101205538; called by muse, mutect2
- GABBR2 | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV99409408; called by muse, mutect2, varscan2
- GABBR2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.028); catalogued as COSV99409045; called by muse, mutect2, varscan2
- GBP2 | c.1769T>C p.I590T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV100975353; called by mutect2, varscan2
- GLI2 | c.1384C>T p.R462W (on ENST00000361492 / NM_001374353.1; = p.R479W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121917708, CM066094, COSV100082563; called by muse, mutect2, varscan2
- GPR149 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV67669078; called by muse, mutect2
- GSE1 | c.3089C>G p.S1030* | Nonsense Mutation (SNP) | VAF 42/130 reads (32%) | catalogued as COSV99496165; called by muse, mutect2, varscan2
- HERC2 | c.7764A>C p.E2588D | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99871537; called by muse, mutect2, varscan2
- HIRIP3 | c.683A>C p.E228A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs747070567, COSV99662887; called by muse, mutect2, varscan2
- HK3 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV99457981; called by muse, mutect2, varscan2
- ITM2C | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100419569; called by muse, mutect2
- ITPR2 | c.4822G>C p.D1608H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101189856; called by muse, mutect2, varscan2
- KAT6A | c.1877G>T p.C626F | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99704533; called by muse, mutect2, varscan2
- KCNQ3 | c.1486A>G p.M496V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101195756; called by muse, mutect2, varscan2
- KCNU1 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 11/341 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101298997, COSV67760032; called by muse, mutect2
- KIAA0319 | c.2160A>T p.R720S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as COSV100985274; called by muse, mutect2, varscan2
- KIAA0319 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs752726173, COSV100985278, COSV100985773; called by muse, mutect2, varscan2
- KIF26B | c.3670T>C p.S1224P | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV100831754; called by muse, mutect2, varscan2
- LAG3 | c.1367T>G p.L456R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99179888; called by muse, mutect2, varscan2
- LTK | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99778675; called by muse, mutect2
- LY75 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99716111; called by muse, mutect2, varscan2
- MCF2 | c.1675A>G p.I559V | Missense Mutation (SNP) | VAF 158/772 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV58493882; called by muse, mutect2, varscan2
- MICAL2 | c.948+1G>T p.X316_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | catalogued as rs754758130, COSV56320971; called by muse, mutect2, varscan2
- MPDZ | c.4460C>T p.P1487L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100056277; called by muse, mutect2, varscan2
- MRPL48 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100057258; called by muse, mutect2, varscan2
- MUC16 | c.23702C>A p.A7901E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV101198542; called by muse, mutect2
- MYH4 | c.4814T>A p.L1605Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1349105101, COSV99700525; called by muse, mutect2, varscan2
- MYH8 | c.4685T>A p.L1562Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV101238292; called by muse, mutect2, varscan2
- NOS1 | c.2904C>A p.S968R | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100500160; called by muse, mutect2
- NOTCH4 | c.2053G>T p.G685W | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900453, COSV66678836; called by muse, mutect2, varscan2
- NPFFR2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100440385, COSV58145977, COSV58149773; called by muse, mutect2
- NR0B1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.355); catalogued as COSV100973467; called by muse, mutect2, varscan2
- NUDT13 | c.41T>C p.F14S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100624685; called by muse, mutect2, varscan2
- NUF2 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 117/622 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV99616188; called by muse, mutect2, varscan2
- OPA1 | c.2368A>T p.I790L (on ENST00000361510 / NM_130837.3; = p.I735L on NM_015560.3) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100655192; called by muse, mutect2, varscan2
- OR14J1 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV101012726; called by muse, mutect2, varscan2
- PCARE | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100527373; called by muse, mutect2, varscan2
- PCNT | c.5479G>T p.A1827S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs563470468, COSV100855119, COSV64026678; called by muse, mutect2, varscan2
- PDLIM5 | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100523400; called by muse, mutect2, varscan2
- PHLDB1 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV100616322; called by muse, mutect2, varscan2
- PLG | c.92del p.A31Vfs*16 | Frame Shift Del (DEL) | VAF 117/612 reads (19%) | catalogued as COSV51983437; called by mutect2, pindel, varscan2
- PRPSAP2 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV99264377; called by muse, mutect2, varscan2
- PTCHD4 | c.1588T>C p.W530R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758740618, COSV100260304; called by muse, mutect2, varscan2
- PTGER3 | c.626T>A p.F209Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138415; called by muse, mutect2, varscan2
- RHOT1 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs755028129, COSV100446960; called by muse, mutect2, varscan2
- RYR2 | c.3878A>C p.Q1293P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV100768587; called by muse, mutect2, varscan2
- SFRP5 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs144307831; called by muse, mutect2
- SH3PXD2B | c.2047G>T p.G683W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100287740; called by muse, mutect2, varscan2
- SIPA1 | c.1607T>A p.L536Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101255777; called by muse, mutect2
- SLC17A6 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99580945; called by muse, mutect2, varscan2
- SLC25A43 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV99474444; called by muse, mutect2, varscan2
- SLC2A12 | c.1645A>C p.I549L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99259728; called by muse, mutect2, varscan2
- TENM1 | c.1406T>A p.V469D | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100949301; called by muse, mutect2, varscan2
- TENM2 | c.8089G>A p.D2697N (on ENST00000518659 / NM_001122679.2; = p.D2458N on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV101318095; called by muse, mutect2
- TMEM176B | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1054061085, COSV99133581; called by muse, mutect2, varscan2
- TMIGD1 | c.232T>A p.S78T | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100187156; called by muse, mutect2, varscan2
- TNFRSF13C | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV99351690; called by muse, mutect2
- TNIP2 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145123249, COSV100198614; called by muse, mutect2
- TNRC18 | c.6860A>C p.Q2287P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100078598; called by muse, varscan2
- TOR3A | c.376T>G p.L126V | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100751252; called by muse, mutect2, varscan2
- TSG101 | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99323761; called by muse, varscan2
- UGT2A3 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.076); catalogued as COSV99279665; called by muse, mutect2, varscan2
- UNC13D | c.2074G>T p.G692C | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99256156; called by muse, mutect2, varscan2
- USH2A | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100230523, COSV56398699; called by muse, mutect2, varscan2
- USP22 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs1208646048, COSV99820106; called by muse, mutect2
- VPS13D | c.2923A>G p.I975V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1432213993, COSV99165658; called by muse, mutect2, varscan2
- WARS2 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99346032; called by muse, mutect2, varscan2
- WSB2 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV99969778; called by muse, mutect2, varscan2
- XIRP2 | c.2888C>A p.T963N (on ENST00000628543; = p.T1138N on NM_152381.6) | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1172983031, COSV99739437; called by muse, mutect2, varscan2
- ZDHHC17 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV100602025; called by muse, mutect2, varscan2
- ZNF135 | c.1498G>A p.G500S (on ENST00000313434 / NM_001289401.2; = p.G512S on NM_003436.4) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs566725358, COSV100536661, COSV57885169; called by muse, mutect2, varscan2
- ZNF563 | c.1290A>T p.L430F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99536416; called by muse, mutect2, varscan2
- BRD7 | c.1389_1390del p.L463Ffs*22 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- COL4A6 | c.206del p.S69Lfs*7 | Frame Shift Del (DEL) | VAF 24/189 reads (13%) | called by mutect2, pindel, varscan2
- DSC2 | c.1236del p.N413Mfs*7 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- PAPSS1 | c.412-6_428del p.X138_splice | Splice Site (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.4223A>G p.Q1408R | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- RPS6KA3 | c.127-24_128del p.X43_splice | Splice Site (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel*
- BDP1 | c.3402G>A p.V1134= | Silent (SNP) | VAF 55/228 reads (24%) | catalogued as COSV100702812; called by muse, mutect2, varscan2
- BTN3A3 | c.1614G>A p.P538= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs757126334, COSV55074378; called by muse, mutect2, varscan2
- CFAP47 | c.327T>A p.P109= | Silent (SNP) | VAF 105/476 reads (22%) | catalogued as COSV99934560; called by mutect2, varscan2
- CHRND | c.222T>A p.T74= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as COSV99285571; called by muse, mutect2, varscan2
- CUBN | c.5454C>A p.L1818= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV100912195, COSV100912629; called by muse, mutect2, varscan2
- CYP2C18 | c.1038C>G p.P346= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV99608326; called by muse, mutect2, varscan2
- DIDO1 | c.516G>T p.R172= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99825025; called by muse, mutect2, varscan2
- EGF | c.552A>G p.R184= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs369090159; called by muse, mutect2, varscan2
- EMILIN2 | c.408T>A p.P136= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs1434873775, COSV99598224; called by muse, mutect2, varscan2
- EXOC7 | c.1092C>T p.Y364= (on ENST00000335146 / NM_001145297.4; = p.Y282= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1316059998, COSV100134927; called by muse, mutect2, varscan2
- FOLH1 | c.102C>T p.L34= | Silent (SNP) | VAF 43/233 reads (18%) | catalogued as COSV99922806; called by muse, mutect2, varscan2
- GCNT1 | c.273C>T p.D91= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as rs139014455; called by muse, mutect2, varscan2
- GLYCTK | c.247C>T p.L83= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs374934931; called by muse, mutect2, varscan2
- GSPT2 | c.501A>G p.G167= | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as COSV100467974; called by muse, mutect2, varscan2
- HOXA6 | c.273G>T p.S91= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV99762133; called by muse, mutect2, varscan2
- JMJD1C | c.1881T>G p.L627= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV101232254; called by muse, mutect2, varscan2
- KRTAP9-3 | c.132G>A p.Q44= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100893136; called by muse, mutect2, varscan2
- LZTS2 | c.1752G>T p.R584= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100932101; called by muse, mutect2
- MACF1 | c.1258C>A p.R420= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV100482988, COSV100486155; called by muse, mutect2, varscan2
- NELFCD | c.1602T>A p.T534= (on ENST00000602795; = p.T516= on NM_198976.4) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99413453; called by muse, mutect2, varscan2
- NIPBL | c.6660A>G p.L2220= | Silent (SNP) | VAF 111/508 reads (22%) | catalogued as COSV99239254; called by muse, mutect2, varscan2
- OR2T2 | c.675T>A p.T225= | Silent (SNP) | VAF 48/391 reads (12%) | catalogued as COSV100737588; called by muse, mutect2, varscan2
- OR5J2 | c.837G>A p.T279= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs764523350, COSV56620876, COSV56622525; called by muse, mutect2, varscan2
- PACRG | c.822C>T p.Y274= | Silent (SNP) | VAF 57/261 reads (22%) | catalogued as rs769427583, COSV61305638; called by muse, mutect2, varscan2
- PLRG1 | c.744T>C p.T248= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV100122998; called by muse, mutect2, varscan2
- PLXNA4 | c.894T>A p.I298= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100322921; called by muse, mutect2, varscan2
- PPP1R42 | c.126A>G p.A42= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as rs1053441106, COSV100221079; called by muse, mutect2
- RIT2 | c.495C>T p.A165= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as COSV100450044; called by muse, mutect2, varscan2
- SEMA3G | c.1755T>A p.L585= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as COSV99202146; called by muse, mutect2, varscan2
- SLC38A2 | c.231A>G p.V77= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV99873776; called by muse, mutect2, varscan2
- SLITRK2 | c.2268T>C p.Y756= | Silent (SNP) | VAF 60/313 reads (19%) | catalogued as COSV100157416; called by muse, mutect2, varscan2
- TTC14 | c.54C>T p.L18= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV56011375; called by muse, mutect2, varscan2
- USP24 | c.1755A>C p.A585= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99599040; called by muse, mutect2, varscan2
- WDR24 | c.2256G>A p.A752= (on ENST00000248142; = p.A622= on NM_032259.4) | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99555470; called by muse, mutect2
- ZNF385B | c.264C>T p.P88= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs370441083; called by muse, mutect2, varscan2
- ZNF484 | c.1830C>T p.C610= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100214497; called by muse, mutect2, varscan2
- ZNF695 | c.990C>A p.G330= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1250964154, COSV100377288; called by muse, mutect2, varscan2
- NBEA | c.7618-367A>G | Intron (SNP) | VAF 39/226 reads (17%) | catalogued as COSV100077448; called by muse, mutect2, varscan2
